Somatic mutation profile of tumor specimen TCGA-QR-A70D-01A (aliquot TCGA-QR-A70D-01A-11D-A35D-08) from TCGA case TCGA-QR-A70D, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Aortic body tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 39.5 years (14,412 days).
Specimen TCGA-QR-A70D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b25f5a6-5c62-44e5-af7a-d389366329ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70D-10B (Blood Derived Normal), aliquot TCGA-QR-A70D-10B-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2214687-ccb7-46af-97d1-5eb372e0eb0c

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 6 silent.
By variant classification: Silent 6, Missense Mutation 4, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ2A | c.413A>G p.H138R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs771328715; called by mutect2, varscan2
- MYH14 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768207483; called by muse, mutect2, varscan2
- ZC3H7B | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs762631126, COSV60961365; called by muse, mutect2, varscan2
- SLC52A1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TAF1 | c.1940C>T p.T647I (on ENST00000373790 / NM_138923.4; = p.T668I on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- COL4A5 | c.4611C>T p.Y1537= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs772136082; called by muse, mutect2, varscan2
- IPO8 | c.1248T>C p.C416= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- KCNH3 | c.1173C>T p.S391= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1001492216; called by muse, mutect2, varscan2
- PIK3CB | c.2793C>T p.G931= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- PRKACA | c.528C>T p.D176= | Silent (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- TMEM236 | c.384C>T p.D128= | Silent (SNP) | VAF 30/466 reads (6%) | called by muse, mutect2
